Somatic mutation profile of tumor specimen TCGA-BR-6565-01A (aliquot TCGA-BR-6565-01A-11D-1800-08) from TCGA case TCGA-BR-6565, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 67.1 years (24,495 days).
Specimen TCGA-BR-6565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cd17880-ab20-4619-b8db-3003bf4d1ac7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6565-10A (Blood Derived Normal), aliquot TCGA-BR-6565-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6977fc8e-fdad-4c39-bd70-7125a30e8a99

The open-access MAF lists 140 somatic variants for this specimen: 107 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 28, Nonsense Mutation 7, Intron 4, Splice Site 4, Splice Region 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 53/124 reads (43%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPR | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as rs779204655, CM123176, COSV52297859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.319T>G p.Y107D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV52679423, COSV53179040; called by muse, mutect2, varscan2
- AC104452.1 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.082); catalogued as COSV55534441; called by muse, mutect2, varscan2
- ADCY8 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs747303557, COSV53909448; called by muse, mutect2, varscan2
- ADGRB1 | c.2613G>C p.E871D | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV60103433; called by muse, mutect2
- ANKRD10 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.994); catalogued as rs766404124, COSV57445435; called by muse, mutect2, varscan2
- APOB | c.3629G>C p.R1210T | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV51952348; called by muse, mutect2
- ARHGEF25 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV54090650, COSV99678135; called by muse, mutect2, varscan2
- ARHGEF39 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV58398469; called by muse, mutect2, varscan2
- ARIH2 | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV62706369; called by muse, mutect2, varscan2
- AVP | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66672228; called by muse, mutect2
- BIRC6 | c.1721C>A p.T574K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.138); catalogued as COSV70205869; called by muse, mutect2, varscan2
- BPNT2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750461430, COSV52909045; called by muse, mutect2, varscan2
- BZW2 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs755081715, COSV51757690; called by muse, mutect2, varscan2
- C18orf54 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs749974011, COSV100266446, COSV55618772; called by muse, mutect2, varscan2
- C4orf19 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV52650312; called by muse, mutect2, varscan2
- CACNA1D | c.3006G>A p.K1002= (on ENST00000350061 / NM_001128840.3; = p.K1022= on NM_000720.4) | Splice Region (SNP) | VAF 12/57 reads (21%) | catalogued as COSV55464880; called by muse, mutect2, varscan2
- CACNB2 | c.1396C>T p.P466S (on ENST00000324631 / NM_201596.3; = p.P411S on NM_000724.4) | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56647067; called by muse, mutect2
- CANT1 | c.908G>C p.S303T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56606753; called by muse, mutect2
- CCDC178 | c.1188G>T p.L396F | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV100285836, COSV55797633, COSV55799534; called by muse, mutect2, varscan2
- CCDC73 | c.2802G>C p.E934D | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV58804878; called by muse, mutect2, varscan2
- CD2BP2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV59769879; called by muse, mutect2, varscan2
- CDKL2 | c.330T>G p.I110M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56735448; called by muse, mutect2, varscan2
- CLCN7 | c.1098+2T>C p.X366_splice | Splice Site (SNP) | VAF 31/126 reads (25%) | catalogued as COSV51973926; called by muse, mutect2, varscan2
- CLIP3 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs758565564, COSV62111824; called by muse, mutect2, varscan2
- CNTNAP4 | c.2935C>T p.P979S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.103); catalogued as COSV56700287; called by muse, mutect2, varscan2
- COL13A1 | c.1259G>A p.R420H (on ENST00000398978 / NM_001130103.2; = p.R363H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as rs372794494; called by mutect2, varscan2
- CSMD2 | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53963159, COSV53978360; called by muse, mutect2
- CSMD3 | c.10315C>G p.Q3439E (on ENST00000297405 / NM_001363185.1; = p.Q3270E on NM_052900.3) | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52319623; called by muse, mutect2
- DDX5 | c.291T>G p.Y97* | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as COSV56751299; called by muse, mutect2, varscan2
- DIP2C | c.2985+1G>T p.X995_splice | Splice Site (SNP) | VAF 8/153 reads (5%) | catalogued as COSV55179061; called by muse, mutect2
- ECD | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100881524, COSV65899008; called by muse, mutect2, varscan2
- EPHA6 | c.2604G>C p.Q868H (on ENST00000389672 / NM_001080448.3; = p.Q260H on NM_173655.4) | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67593956; called by muse, mutect2
- FAT2 | c.9316G>C p.V3106L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV55829367; called by muse, mutect2, varscan2
- FBN3 | c.7528C>T p.R2510C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs375723933; called by muse, mutect2, varscan2
- FCGBP | c.5575G>C p.G1859R | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1488537780; called by muse, mutect2
- FLNA | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs781827791, COSV61051655; ClinVar: uncertain significance; called by muse, mutect2
- GFPT1 | c.1154G>A p.R385Q (on ENST00000357308 / NM_001244710.2; = p.R367Q on NM_002056.4) | Missense Mutation (SNP) | VAF 36/423 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV61950776; called by muse, mutect2
- GJA5 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs782627991, COSV54786591; called by muse, mutect2, varscan2
- GPR32 | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV54515589, COSV99567100; called by muse, mutect2, varscan2
- H3C4 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as COSV61912415; called by muse, mutect2, varscan2
- HGFAC | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV58757146; called by muse, mutect2, varscan2
- HOOK3 | c.1996G>C p.V666L | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56878821, COSV56887866; called by muse, mutect2
- IGSF9 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as COSV63642526; called by muse, mutect2, varscan2
- KIF14 | c.1174C>G p.H392D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV66264121; called by muse, mutect2, varscan2
- KRT33B | c.118A>T p.N40Y | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99290866; called by muse, mutect2
- LRGUK | c.1420A>T p.M474L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.43); catalogued as COSV53643801; called by muse, mutect2, varscan2
- LRP1B | c.3398G>A p.S1133N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV67274916; called by muse, mutect2
- LRRC18 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757556824, COSV53285979; called by mutect2, varscan2
- LRRN3 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV57823948; called by muse, mutect2
- MFN2 | c.2187C>G p.S729R | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as COSV52423505, COSV52425594; called by muse, mutect2
- MOGS | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV51971709; called by muse, mutect2, varscan2
- MSS51 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV55020683; called by muse, mutect2, varscan2
- MYH10 | c.2846A>C p.Q949P | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV52611310; called by muse, mutect2
- NAV3 | c.244-2A>G p.X82_splice | Splice Site (SNP) | VAF 14/267 reads (5%) | catalogued as COSV57111983; called by muse, mutect2
- NAV3 | c.5378C>A p.T1793K (on ENST00000397909 / NM_001024383.2; = p.T1771K on NM_014903.6) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.894); catalogued as COSV57111999; called by muse, mutect2
- NBEA | c.7834A>G p.I2612V | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV59822779; called by muse, mutect2
- NBEAL2 | c.4484G>C p.S1495T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.186); catalogued as COSV52762828; called by muse, mutect2, varscan2
- NEUROD4 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54470799, COSV54472887; called by muse, mutect2, varscan2
- NIBAN1 | c.1064T>C p.M355T | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62287710; called by muse, mutect2
- NNT | c.2051G>A p.G684D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52929743; called by muse, mutect2, varscan2
- NR2F2 | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV67684141; called by muse, mutect2, varscan2
- NSD1 | c.1732G>T p.A578S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.057); catalogued as COSV61784710; called by muse, mutect2, varscan2
- NTMT1 | c.420C>G p.H140Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52965906; called by muse, mutect2
- NUP153 | c.2894C>G p.S965C | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV50465471; called by muse, mutect2
- OR2J2 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs1470113846, COSV65848393; called by muse, mutect2
- OR2L3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs755534000, COSV63456299; called by muse, varscan2
- OR4N2 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60054444, COSV60054920; called by muse, mutect2
- OVCH1 | c.3041C>G p.P1014R | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58968110; called by muse, mutect2
- PCDHA8 | c.1855C>A p.R619S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); catalogued as rs145175505, COSV65323207, COSV65332790; called by muse, mutect2, varscan2
- PCDHGB3 | c.1835G>A p.S612N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV54033412; called by muse, mutect2, varscan2
- PCDHGC5 | c.2114C>G p.S705C | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV52768282; called by muse, mutect2, varscan2
- PHRF1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52762676; called by muse, mutect2, varscan2
- PHRF1 | c.1808A>G p.D603G (on ENST00000264555 / NM_001286581.2; = p.D602G on NM_020901.4) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV52762693; called by muse, mutect2, varscan2
- PLCD3 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV59558581; called by muse, mutect2, varscan2
- PLPPR4 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100926709, COSV64567728; called by muse, mutect2, varscan2
- PPARGC1A | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53533594; called by muse, mutect2, varscan2
- PRDM9 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV57002253, COSV57005862; called by muse, mutect2, varscan2
- PRR27 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV60641480; called by mutect2, varscan2
- PTPRD | c.5710C>G p.L1904V | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV61981581; called by muse, mutect2, varscan2
- RASGEF1B | c.623C>G p.T208R | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV52337376, COSV52339612; called by muse, mutect2, varscan2
- SCUBE2 | c.2693G>A p.R898Q (on ENST00000649792 / NM_001367977.2; = p.R841Q on NM_020974.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762446913, COSV58546796; called by muse, mutect2, varscan2
- SF3B2 | c.1451A>T p.D484V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59430079; called by muse, mutect2, varscan2
- SHC3 | c.730-1G>T p.X244_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV65440813; called by muse, mutect2, varscan2
- SLCO4C1 | c.264C>G p.Y88* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV60515298, COSV60520287; called by muse, mutect2
- SOCS3 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100434544, COSV58270499; called by muse, mutect2, varscan2
- SOCS3 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58270364; called by muse, mutect2, varscan2
- SOS2 | c.3436C>T p.P1146S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV53574430; called by muse, mutect2, varscan2
- SPTBN4 | c.7385G>T p.G2462V | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.755); catalogued as COSV52543791; called by muse, mutect2, varscan2
- SYNE1 | c.11816T>C p.L3939P | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55101684; called by muse, mutect2, varscan2
- TCIRG1 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs61730880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEKT4 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs75859449, COSV54628543; called by muse, mutect2
- TMPPE | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1040086951, COSV56568034; called by muse, mutect2, varscan2
- TNNT2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs778730615, COSV52665367; called by mutect2, varscan2
- TNS1 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV50768454; called by muse, mutect2, varscan2
- TPO | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV61111338; called by muse, mutect2
- TRPV4 | c.1430C>A p.S477Y | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV55685741; called by muse, mutect2, varscan2
- USF3 | c.3294C>G p.F1098L | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57077387; called by muse, mutect2, varscan2
- USP51 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV72351953; called by muse, mutect2, varscan2
- UTP20 | c.891A>G p.Q297= | Splice Region (SNP) | VAF 10/69 reads (14%) | catalogued as COSV55385376; called by muse, mutect2, varscan2
- WNT1 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53296913; called by muse, mutect2, varscan2
- ZNF175 | c.2054A>G p.N685S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1454122209, COSV51798418; called by muse, mutect2, varscan2
- ACACA | c.6715A>G p.I2239V | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2
- CEP162 | c.3293dup p.R1099Efs*46 | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- PLOD3 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2
- TPTE | c.1536A>C p.K512N (on ENST00000618007 / NM_199261.4; = p.K494N on NM_199259.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- ADAMTS1 | c.1800C>G p.G600= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as COSV53173454; called by muse, mutect2, varscan2
- AKAP6 | c.3786C>T p.D1262= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs749053344, COSV55208721; called by muse, mutect2, varscan2
- CENPE | c.1188C>T p.N396= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV99479233; called by muse, mutect2
- COL11A1 | c.333T>A p.I111= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV62197463; called by muse, mutect2, varscan2
- DYNC2H1 | c.3903G>A p.Q1301= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV62095241, COSV62106777; called by muse, mutect2
- EXPH5 | c.2466C>T p.F822= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as COSV56208292; called by muse, mutect2
- FBXO30 | c.1383T>C p.F461= | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as COSV52792402; called by muse, mutect2
- FLT4 | c.4050C>A p.S1350= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99989139; called by muse, mutect2
- FRMD7 | c.1806T>G p.P602= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV53748894; called by muse, mutect2, varscan2
- GNG12 | c.99G>A p.S33= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs763599665, COSV63974249; called by muse, mutect2, varscan2
- HIVEP1 | c.498T>C p.S166= | Silent (SNP) | VAF 57/203 reads (28%) | catalogued as COSV65105071; called by muse, mutect2, varscan2
- HTR1E | c.864G>A p.K288= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV59511097; called by muse, mutect2
- KIAA2026 | c.1257C>T p.H419= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs750531915, COSV67357762; called by muse, mutect2, varscan2
- LGALSL | c.459G>A p.T153= | Silent (SNP) | VAF 17/210 reads (8%) | catalogued as rs778858238, COSV53230946; called by muse, mutect2
- MUC17 | c.10659A>G p.Q3553= | Silent (SNP) | VAF 69/469 reads (15%) | catalogued as COSV60303348; called by muse, mutect2, varscan2
- NPAP1 | c.84G>A p.L28= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV61511166; called by muse, mutect2, varscan2
- OR5M8 | c.777C>T p.L259= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV59116064; called by muse, mutect2, varscan2
- PDZRN3 | c.2610C>T p.H870= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV55209796, COSV55211452, COSV55215426; called by muse, mutect2, varscan2
- PHF3 | c.4842T>C p.S1614= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV50341821; called by muse, mutect2, varscan2
- POF1B | c.774A>C p.G258= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV53140647; called by muse, mutect2
- RBP1 | c.393C>T p.F131= (on ENST00000619087 / NM_001365940.2; = p.F193= on NM_002899.5) | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as COSV51678591; called by muse, mutect2, varscan2
- RTN4RL2 | c.996C>T p.Y332= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV58653051; called by mutect2, varscan2
- SLC2A3 | c.1410C>T p.H470= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as rs146012904; called by muse, mutect2
- SYNE1 | c.12483T>C p.S4161= (on ENST00000367255 / NM_182961.4; = p.S4090= on NM_033071.3) | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV55101626, COSV99571261; called by muse, mutect2, varscan2
- TBX19 | c.330C>T p.P110= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs148222296; called by muse, mutect2, varscan2
- USP26 | c.429T>G p.S143= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV63709823; called by muse, mutect2, varscan2
- USP36 | c.1965A>G p.P655= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV61754443; called by muse, mutect2, varscan2
- WIZ | c.4098C>T p.P1366= (on ENST00000673675 / NM_001371589.1; = p.P271= on NM_021241.3) | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV54607312, COSV54612594; called by muse, mutect2
- AIRE | c.880-216G>C | Intron (SNP) | VAF 12/116 reads (10%) | catalogued as COSV99380978, COSV99381444; called by muse, mutect2
- DLC1 | c.1348+90531A>T | Intron (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99365669; called by muse, mutect2, varscan2
- MAP4 | c.1999+4990G>A | Intron (SNP) | VAF 16/126 reads (13%) | catalogued as rs1254658548, COSV53144493; called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21172398 T>A | 5'Flank (SNP) | VAF 9/85 reads (11%) | catalogued as COSV101346369; called by muse, mutect2
- TP53AIP1 | c.141+74G>C | Intron (SNP) | VAF 10/70 reads (14%) | catalogued as COSV101513116; called by muse, mutect2, varscan2
